Gene-level copy-number profile of tumor specimen HCM-SANG-0289-C15-01B from HCMI case HCM-SANG-0289-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-0289-C15-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fb8992ae-ae76-44bc-ae2d-637c2846e503.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0289-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/24e20e9f-dfcb-4dae-bb3a-1cb90f84c73b

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 1,140; copy number 1: 31,586; copy number 2: 24,269; copy number 3: 1,679; copy number 4: 56; copy number 5: 48; copy number 6: 2; copy number 7: 72; copy number 8: 41; copy number 9: 2; copy number 10: 2; copy number 12: 4; copy number 46: 5.

Homozygous deletions (total copy number 0; autosomes only): 637 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–49,589,529, 12 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr4:90,370,123–90,370,427, 1 gene (within-gene range 0–1): RN7SKP248.
- chr17:16,690,261–16,804,453, 1 gene (within-gene range 0–1): AC098850.3.
- chr17:16,786,489–16,852,777, 11 genes: USP32P1, SRP68P1, AC098850.4, AC098850.1, FAM106C, AC022596.1, NOS2P4, KRT16P6, KRT16P2, KRT17P1, KRT17P4.
- chr18:36,108,531–40,144,504, 37 genes: SLC39A6, ELP2, AC023043.1, MOCOS, AC023043.4, AC023043.2, AC023043.3, FHOD3, AC055840.1, TPGS2, KIAA1328, AC016493.1, AC015961.1, CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1, MIR4318, RPL12P40, AC100781.1, RN7SKP182, RNU6-706P, MIR924HG, AC011139.1, RPL7AP66, MIR924, AC099845.1, MIR5583-2, MIR5583-1, RNU6-1242P, LINC01901, LINC01902, AC011266.1, LINC01477, RPL17P45.
- chr18:43,499,173–80,247,514, 543 genes (broad region; genes not listed).
- chr20:14,933,843–15,022,958, 3 genes (within-gene range 0–1): AL138808.1, RNU6-1159P, RNU6-115P.
- chr21:7,744,962–8,701,562, 29 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2, CR381572.1.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 1,911 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:47,831,330–49,062,081, 22 genes, copy number 3: AC107068.2, AC107068.1, NFXL1, NIPAL1, CNGA1, TXK, RNU6-838P, U6, TEC, Y_RNA, SLAIN2, SLC10A4, ZAR1, FRYL, RNU5E-3P, OCIAD1, OCIAD1-AS1, OCIAD2, RNU6-158P, AC020593.1, CWH43, TPI1P4.
- chr4:137,301,001–144,343,750, 107 genes, copy number 3 (broad region; genes not listed).
- chr6:45,328,157–45,664,349, 1 gene, copy number 3 (within-gene range 2–3): RUNX2.
- chr6:45,573,346–50,913,256, 70 genes, copy number 3 (broad region; genes not listed).
- chr8:11,486,894–11,839,304, 9 genes, copy number 9–46: BLK, AC022239.1, LINC00208, GATA4, C8orf49, NEIL2, SUB1P1, FDFT1, AC069185.1.
- chr8:12,570,350–12,581,063, 2 genes, copy number 5: RPS3AP34, AC068587.2.
- chr8:29,067,278–29,263,124, 1 gene, copy number 8 (within-gene range 1–8): KIF13B.
- chr8:29,110,573–30,385,401, 34 genes, copy number 4–8 (within-gene range 2–8): AC108449.1, HMGB1P23, DUSP4, AC084262.2, AC084262.1, AC084026.2, AC084026.1, AC084026.3, RPL17P33, LINC00589, LINC02099, AC131254.1, AC131254.3, AC131254.2, LINC02209, MIR3148, MAP2K1P1, RNU6-1218P, SARAF, AC044849.1, LEPROTL1, RPS15AP24, MBOAT4, AC026979.2, DCTN6, AC026979.1, AC026979.4, AC026979.3, HSPA8P11, AC090820.1, AC109329.1, PPIAP84, TUBBP1, RBPMS-AS1.
- chr8:37,784,191–38,213,301, 21 genes, copy number 8: ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2.
- chr8:39,743,735–42,271,266, 51 genes, copy number 3–5: ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1, SIRLNT, AC105999.1, AC010857.1, ZMAT4, AC048387.1, RNU6-356P, SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P, SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1.
- chr8:112,222,928–113,436,939, 2 genes, copy number 3 (within-gene range 2–3): CSMD3, AC024996.1.
- chr8:113,376,669–137,105,458, 286 genes, copy number 3–4 (broad region; genes not listed).
- chr10:32,887,273–37,544,701, 67 genes, copy number 5–12 (broad region; genes not listed).
- chr12:12,310–32,107,528, 794 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr12:53,632,726–64,162,217, 338 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr12:105,107,324–105,396,097, 5 genes, copy number 3: WASHC4, APPL2, C12orf75, AC078874.1, KCCAT198.
- chr13:19,863,858–20,103,230, 5 genes, copy number 3: AL355001.2, ZMYM2, KRR1P1, AL138688.2, LINC01072.
- chr13:21,216,555–21,704,498, 17 genes, copy number 3: AL158032.1, LINC01046, ESRRAP2, AL158032.2, MIPEPP3, LINC00539, GRK6P1, GAPDHP52, RNA5SP25, ZDHHC20, ZDHHC20-IT1, H2BP6, MICU2, FNTAP2, RNU6-59P, RPS7P10, FGF9.
- chr13:22,040,972–22,276,526, 3 genes, copy number 4: LINC00540, NME1P1, MTND3P1.
- chr14:18,333,726–18,419,273, 4 genes, copy number 4: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr14:37,556,158–37,596,059, 3 genes, copy number 3 (within-gene range 2–3): AL121790.2, AL121790.1, FOXA1.
- chr17:18,390,153–18,551,705, 16 genes, copy number 3 (within-gene range 1–3): AL353997.5, TBC1D3P4, LINC02076, KRT17P5, YWHAEP2, KRT17P2, KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.
- chr18:21,529,284–23,026,488, 41 genes, copy number 3–8: ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA.
- chr21:13,609,858–13,777,266, 12 genes, copy number 3: POTED, RNU6-286P, MIR3118-1, AL050303.2, GRAMD4P1, CXADRP1, AL050303.3, LONRF2P5, MIR8069-2, FEM1AP1, AL050303.1, TERF1P1.

Autosomal genes at a single copy (total copy number 1): 29,233. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
